Surgical pathology report (de-identified scan), TCGA case TCGA-D9-A3Z4, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D9-A3Z4-01A (Primary Tumor).

Department of Cancer Pathology

Patient: XXX : XXX Age: Gender:

Examination result

Unit in charge:

Physician in charge:

Clinical diagnosis (suspicion): **Skin melanoma on the right arm**

Date of admission: (urgency: Standard)

Material:

1) Material: skin of the arm, Method of collection: Lesion resection.

Histopathological diagnosis:

Examination performed on:

**Malignant melanoma of the skin with ulceration.
pT4b, pN3.**

12 mm, diameter 24 mm.

Macroscopic description:

A flap of skin with subcutaneous tissue sized: 18 x 8 x 2 cm. Tumour sized 2.4 x 2.4 x 1 cm on the skin, brown-coloured, ulcerous, placed 1 cm from the base and 2 cm from the side edge.
Small satellite tumours on the skin from 0.1 to 0.6 cm (side margin 0.6 cm, from the base 0.4 cm).
Proliferation sized 3 x 1.7 x 3.5 cm in the subcutaneous tissue, reaching the base.

Microscopic description:

Malignant melanoma of the skin

Clinical data and histology suggestive of a primary lesion – nodular type.

Level V according to , thickness of 12 mm acc. to , the largest tumour size is 24 mm. A faint lymphocitary proliferation at the foot of the lesion, no signs of regression. Ulceration and satellite lesions. No remnants of the pre-existing naevus.

Minimum margin of healthy tissues to the side of the surgical specimen: 0.3 cm Minimum margin of healthy tissues from the base of the surgical specimen: 0 cm.

Assistant:

Pathologist: :

Edited by

CONTACT YOUR DOCTOR WITH THIS REPORT!

ICD-O-3
melanoma, Nos
8720/3
Site: skin, arm
C44.6
6-6-12
RP

Staging Discrepancy		X
Metastatic/Synchronous Primary		X

6/5/12

Source: NCI Genomic Data Commons file 1d893491-da12-475e-b3ec-32de48a4221e (TCGA-D9-A3Z4.48B52D74-74EA-43BE-918A-4A4E3BDB76B7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).